Surgical pathology report (de-identified scan), TCGA case TCGA-78-7166, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Prince Charles Hospital, specimen TCGA-78-7166-01A (Primary Tumor).

[page 1 of 2]
HISTORY

Left lower lobe and node biopsy. Lung Ca.
Lingular node, No. 11 node, segment of lower lobe.

MACROSCOPIC

Four specimens received.

1: The specimen is labelled "left lower lobe" and consists of a left lower lobe which measures approximately 120 x 130 x 100 mm in maximum dimension. On palpation of the lower zone of the lobe there is a firm to hard mass which has caused some puckering of the pleural surface of the base of the lobe. The pleural surface surrounding the rest of this firm to hard area has a pale brown, slightly nodular, appearance compared to the normal appearing pleura. On sectioning there is a well-defined greyish-brown solid mass which has a mucoid cut surface. It measures 75 x 60 mm in maximum dimension. The tumour appears well clear of the bronchial resection margin by at least 40 mm. Distant lung parenchyma has a collapsed mottled pinkish-grey appearance. [1A, bronchial resection margin; 1B, hilar lymph nodes; 1C-F, tumour with nearest pleural surface; 1G-H, tumour with pleural puckering 1I, distant uninvolved lung parenchyma].

2: The specimen is labelled with patient's details only and consists of an irregular portion of lung, 33 x 25 x 22 mm, bearing a stapled margin, 30 mm in length. The remainder of the specimen is largely covered by pleura, but on the opposite side to the stapled margin, there is a "bare area" approximately 30 x 15 mm. The stapled resection margin has been removed and the bare areas inked. Serial parallel slicing reveals lung parenchyma in which there is evidence of emphysema but no mass lesions are identified and there is no definite evidence of fibrosis. [3 representative TS, 2A-B].

3: The specimen is labelled "lingular node" and consists of three fragments of firm cream and grey tissue ranging from 4-11 mm in greatest diameter. [Wrapped and blocked in toto, 3A].

4: The specimen is labelled "No. 11 lymph node" and consists of three portions of firm grey and cream tissue ranging from 2 mm in diameter to 15 x 10 x 5 mm. [The largest specimen is bisected longitudinally and all tissue wrapped and BIT, 4A].

MICROSCOPY

1: Sections show a well differentiated mucinous adenocarcinoma. The lesion is subpleural but definite pleural invasion is not identified. Special stains are being performed to confirm this. There is no blood vessel invasion and no lymphatic permeation is seen. No perineural permeation is identified. The lesion is clear of the bronchial resection margin but there is squamous metaplasia and severe dysplasia at the resection margin. Hilar lymph node metastases of adenocarcinoma are seen. The lung away from the tumour shows evidence of centriacinar emphysema.

2: Sections show marked centriacinar emphysema. Around some bronchovascular bundles, there is a mild chronic inflammatory cell infiltrate including lymphoid follicles. There is no evidence of squamous metaplasia, dysplasia or malignancy.

3: Sections of the lymph node show scattered deposits of metastatic mucinous adenocarcinoma.

4: Sections of the lymph node show scattered deposits of metastatic mucinous adenocarcinoma.

SUMMARY

Left lower lobe lung and lymph nodes:

- 1: Well differentiated adenocarcinoma; 75 mm in maximal dimension.
- 2: No blood vessel, lymphatic or perineural invasion seen.
- 3: No pleural invasion identified; clear of bronchial margin.
- 4: Hilar, lingular and No 11 lymph node metastases.
- 5: T2N1MX
- 6: Squamous metaplasia and severe dysplasia at bronchial resection margin.
- 7: No involvement of separate piece of lung; centriacinar emphysema present.

[page 2 of 2]
Note this is an amended report.

SUPPLEMENTARY REPORT

There is no invasion of the visceral pleura with elastin stains.

T-28000 M-81403 P1-03000

Copies:

Source: NCI Genomic Data Commons file 9c41ebd7-70f2-46c7-8711-f2a53772344b (TCGA-78-7166.E2DDC3BA-8151-4F3E-9219-CD3147EA5029.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).